Surgical pathology report (de-identified scan), TCGA case TCGA-06-5415, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-5415-01A (Primary Tumor).

[page 1 of 2]
TCGA-06-5415

CLINICAL HISTORY

[REDACTED] and on imaging was found to have a left temporal intra axial, enhancing mass that was diagnosed as glioblastoma. There is residual tumor with mass effect.

OPERATIVE DIAGNOSES

[REDACTED] Brain tumor.

Operation/Specimen: A: Brain, excision

PATHOLOGICAL DIAGNOSIS:

Brain, site not specified, excision:

1. Malignant glioma.
2. Hyalinizing/reactive vasculopathy and necrosis.
- See Comment.

COMMENT

The sections contain small fragments of a malignant glioma that has mitotic figures and microvascular proliferation. There are also larger fragments of necrotic tumor. The vasculature is focally hyalinized and/or has reactive changes. Throughout the viable specimen there is prominent phagocytic activity. The findings are interpreted as viable and necrotic high histological grade glioma, and necrosis and vasculopathy associated with radiation injury.

Electronically Signed Out

[REDACTED]

A.Brain, excision biopsy:
CONTAINER LABEL: brain tumor.
FIXATIVE: Fresh. NO. PIECES: few tan-white fragments. SIZE/VOL: aggregate 21
x 16 x 3 mm. CASSETTES: 1, [REDACTED] [REDACTED] [REDACTED]
[REDACTED]

[page 2 of 2]
ICD-9(s):
191.9 191.9

Histo Data

Part A: Brain, excision

Taken: [REDACTED]

Stain/cnt

H/E x 1

Received: [REDACTED]

Block

Ordered

Comment

1

*** End of Report ***

Source: NCI Genomic Data Commons file 0e6d2116-5267-4a9a-a141-6bf2416d5788 (TCGA-06-5415.9821B6B4-E3F3-4332-9AAC-3FC1E871453C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).